Somatic mutation profile of tumor specimen ASCProject_0064_T2_WES (aliquot ASCProject_0064_T2_WES_1) from CMI case ASCProject_0064, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 32.7 years (11,942 days).
Specimen ASCProject_0064_T2_WES: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 001a67ed-bb77-4997-9ba0-9804c3ada761.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0064_SALIVA (Saliva), aliquot ASCProject_0064_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5715ec89-6245-488a-bfe0-d8d73eca4d2c

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYP | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.174); called by muse, mutect2
- XPO1 | c.686T>A p.L229* | Nonsense Mutation (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
